Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1L2, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1L2-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED]
CC: [REDACTED]

....

Specimens Submitted:

1: SP: Right retroperitoneal mass

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT RETROPERITONEAL MASS; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA.
- NONLIPOGENIC COMPONENT HAS THE APPEARANCE OF PLEOMORPHIC AND SPINDLE CELL HIGH GRADE SARCOMA AND FOCALLY RESEMBLES MYXOFIBROSARCOMA.
- TUMOR MEASURES 12.5 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE, AND SHOWS ABOUT 5% NECROSIS (GROSS ESTIMATE).
- TUMOR COMES WITHIN 0.03 CM OF UNDESIGNATED INKED MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "right retroperitoneal mass with flank musculature" and consists of an unoriented soft, lobulated mass measuring 12.5 x 7.5 x 7 cm with attached skeletal muscle and adipose tissue, overall measuring 22.5 x 14.5 x 6.2 cm. The attached skeletal muscle measures 11 x 9 x 1.5 cm. The mass is covered by an intact thin membranous tissue. The outer surface is inked black and the specimen is sectioned to reveal a lobulated, tan, gelatinous cut surface with intervening fibrous septa and a focus of hemorrhage and necrosis (approximately 10% necrosis). Immediately adjacent to the necrotic area is a more firm, white focus, making up less than 10% of the mass. The mass is less than 0.1 cm from the inked surface and does not grossly involve the

** Continued on next page **

ICD-0-3

Dedifferentiated liposarcoma 8858/3

Site: Retroperitoneum C48.0

2/21/11
lw

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo

----- Page 2 of 2

attached skeletal muscle or fibroadipose tissue. Representative sections are submitted. TPS and gross photographs are taken.

Summary of sections:

MI - mass with ink

MM - mass with skeletal muscle

FA - sections from more firm white area

M - sections from gelatinous areas

FT - uninvolved fibroadipose tissue

Summary of Sections:

Part 1: SP: Right retroperitoneal mass

Block	Sect.	Site	PCs
5		fa	5
1		ft	1
4		m	4
3		mi	3
2		mm	2

**** End of Report ****

Source: NCI Genomic Data Commons file 14819a26-39d7-470a-a34f-6cc4b20a5370 (TCGA-DX-A1L2.28348067-E6A5-4758-9491-2A8609CFFCE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).